Somatic mutation profile of tumor specimen TCGA-ER-A2ND-06A (aliquot TCGA-ER-A2ND-06A-11D-A196-08) from TCGA case TCGA-ER-A2ND, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.9 years (21,520 days).
Specimen TCGA-ER-A2ND-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f24b973-024d-40a3-ab44-795580a13aa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A2ND-10A (Blood Derived Normal), aliquot TCGA-ER-A2ND-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9be307ef-18b4-460c-8286-026cc90d9404

The open-access MAF lists 124 somatic variants for this specimen: 89 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 32, Nonsense Mutation 3, RNA 2, 3'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACAD10 | c.1820A>T p.E607V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV58154696; called by muse, mutect2, varscan2
- ADGRV1 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67980007; called by muse, mutect2, varscan2
- AKAP4 | c.627T>G p.D209E | Missense Mutation (SNP) | VAF 160/220 reads (73%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV62073904; called by muse, mutect2, varscan2
- ALDH18A1 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64662204; called by muse, mutect2, varscan2
- ALPG | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54965236, COSV54965746; called by muse, mutect2, varscan2
- ALPI | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55013765; called by muse, mutect2, varscan2
- ARGFX | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV57681751; called by muse, mutect2, varscan2
- ARHGEF15 | c.377C>A p.S126* | Nonsense Mutation (SNP) | VAF 22/218 reads (10%) | catalogued as COSV62724560; called by muse, mutect2, varscan2
- BAIAP3 | c.1343A>G p.N448S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV60977886; called by muse, mutect2, varscan2
- BCL9L | c.4279C>T p.L1427F | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV52682677; called by muse, mutect2, varscan2
- C1orf198 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV64174713; called by muse, mutect2, varscan2
- C8orf34 | c.809T>C p.I270T | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs1241260277, COSV61373211; called by muse, mutect2, varscan2
- CACNA1S | c.3753A>C p.E1251D | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV62937121; called by muse, mutect2, varscan2
- CCDC178 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV55763607, COSV55800873; called by muse, mutect2, varscan2
- CCDC88B | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV100105952, COSV57265204; called by muse, mutect2, varscan2
- CPXM2 | c.1628C>A p.P543H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs781155643, COSV53857764; called by muse, mutect2, varscan2
- DPYD | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs201615754, COSV64592140; called by muse, mutect2, varscan2
- DSCAM | c.3485G>A p.S1162N | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV68022475; called by muse, mutect2, varscan2
- ELAPOR1 | c.2975G>A p.R992K | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.269); catalogued as COSV64040079, COSV64041418; called by muse, mutect2, varscan2
- EMP2 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63995640; called by muse, mutect2, varscan2
- ETV3L | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760882467, COSV71900997; called by muse, mutect2, varscan2
- EVPL | c.2126A>G p.N709S | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV56908412; called by muse, mutect2, varscan2
- FAM216B | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV58270103; called by muse, mutect2, varscan2
- FBRS | c.692C>T p.P231L (on ENST00000287468; = p.P751L on NM_001105079.3) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54915091; called by muse, mutect2, varscan2
- FILIP1 | c.1700A>G p.N567S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759069261, COSV52724289; called by muse, mutect2, varscan2
- FOSL2 | c.305T>G p.V102G | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.915); catalogued as COSV53103634; called by muse, mutect2, varscan2
- GGT7 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60539971; called by muse, mutect2, varscan2
- GIMAP1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs780854861, COSV56187021; called by mutect2, varscan2
- GUCY2D | c.2795T>G p.M932R | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs766418901, COSV54694814; called by muse, mutect2, varscan2
- HJURP | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 97/133 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs368262451, COSV64978577; called by muse, mutect2, varscan2
- IGF2R | c.5699G>A p.G1900D | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV63626944; called by muse, mutect2, varscan2
- ITGB8 | c.2140A>G p.N714D | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV56005810; called by muse, mutect2, varscan2
- KDM4D | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 77/103 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782491473, COSV100624204, COSV58633888; called by muse, mutect2, varscan2
- KLHL20 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV52940686; called by muse, mutect2, varscan2
- LRP1B | c.9283G>A p.D3095N | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67195375; called by muse, mutect2, varscan2
- MAGEC1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 149/294 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.403); catalogued as COSV53569258; called by muse, mutect2, varscan2
- MGP | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57454090; called by muse, mutect2, varscan2
- MYH13 | c.5153A>C p.Q1718P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs781329038, COSV52822491; called by muse, mutect2, varscan2
- MYH8 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs1294198951, COSV67959934, COSV67961150; called by muse, mutect2, varscan2
- MYOF | c.4541C>G p.P1514R | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63701373; called by muse, mutect2
- NCOA6 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV62861889; called by muse, mutect2, varscan2
- NECTIN4 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV63512127; called by muse, mutect2, varscan2
- NKAIN2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV63699073; called by muse, mutect2, varscan2
- NKX2-3 | c.137T>G p.M46R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV60728416; called by muse, mutect2, varscan2
- NLGN1 | c.1759C>T p.H587Y | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.637); catalogued as COSV64325713; called by muse, mutect2, varscan2
- NLRP4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as rs762952821, COSV56709795; called by muse, mutect2, varscan2
- NPHP1 | c.784T>A p.C262S | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57207014; called by muse, mutect2, varscan2
- NYAP1 | c.946A>G p.T316A | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.55); catalogued as COSV55717654; called by muse, mutect2, varscan2
- OR10R2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV63768558; called by muse, mutect2, varscan2
- OR2AK2 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63549396; called by muse, mutect2, varscan2
- OR2J2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 154/311 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV65847802; called by muse, mutect2, varscan2
- OR4K1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV53458965, COSV99578828; called by muse, mutect2, varscan2
- OTOF | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.095); catalogued as rs763274859, COSV55497831, COSV99719154; called by muse, mutect2, varscan2
- PCDHGA11 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 44/69 reads (64%) | catalogued as rs764642401, COSV53909030; called by muse, mutect2, varscan2
- PDGFRL | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 121/157 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as rs770581489, COSV52411065; called by muse, mutect2, varscan2
- PDPN | c.482C>T p.S161L (on ENST00000621990; = p.S237L on NM_006474.4) | Missense Mutation (SNP) | VAF 52/86 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs202137788; called by muse, mutect2, varscan2
- PHF21A | c.649C>A p.Q217K (on ENST00000418153 / NM_001101802.3; = p.Q218K on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57650654; called by muse, mutect2, varscan2
- PLEKHA8 | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV51649354; called by muse, mutect2, varscan2
- PLXNA1 | c.2782A>C p.S928R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.11); catalogued as COSV52523162; called by muse, mutect2
- POGZ | c.1501A>C p.K501Q | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55033176, COSV99652642; called by muse, mutect2
- PPARGC1B | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.097); catalogued as rs760246140, COSV58527032; called by muse, mutect2, varscan2
- PPP1R3D | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as rs750284106, COSV62563996; called by muse, mutect2, varscan2
- PSG1 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 107/491 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54945926; called by muse, mutect2, varscan2
- REV3L | c.4484C>T p.S1495L | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs375270564; called by muse, mutect2, varscan2
- SALL2 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100444183, COSV58102417; called by muse, mutect2, varscan2
- SCAI | c.1150T>C p.Y384H (on ENST00000336505 / NM_001144877.3; = p.Y407H on NM_173690.5) | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60610579; called by muse, mutect2, varscan2
- SLC17A5 | c.1132T>C p.F378L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as COSV63287186; called by muse, mutect2, varscan2
- SLC44A2 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs1395706959, COSV59835503; called by muse, mutect2, varscan2
- SLC6A9 | c.1580T>A p.M527K (on ENST00000360584 / NM_201649.4; = p.M473K on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV62210038; called by muse, mutect2, varscan2
- SLC7A8 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57553285; called by muse, mutect2, varscan2
- SPINK4 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV65687855; called by muse, mutect2, varscan2
- SRPX | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV59437488; called by muse, mutect2, varscan2
- SUGP2 | c.1927A>G p.N643D | Missense Mutation (SNP) | VAF 69/378 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV58256086; called by muse, mutect2, varscan2
- SULT1A1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs776198283, COSV59087012; called by muse, mutect2, varscan2
- TEKT1 | c.257A>T p.N86I | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs143710127; called by muse, mutect2, varscan2
- TINAG | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as rs770185987, COSV52505299; called by muse, mutect2, varscan2
- TNC | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1001018826, COSV60781584; called by muse, mutect2, varscan2
- TRPM1 | c.1506A>T p.T502= | Splice Region (SNP) | VAF 56/185 reads (30%) | catalogued as COSV56631522; called by muse, mutect2, varscan2
- TRPM6 | c.4882A>G p.T1628A | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV62504442; called by muse, mutect2, varscan2
- TTN | c.51427C>T p.R17143C (on ENST00000591111; = p.R9719C on NM_003319.4) | Missense Mutation (SNP) | VAF 54/75 reads (72%) | PolyPhen probably damaging (0.966); catalogued as rs774740211, COSV59906570; called by muse, mutect2, varscan2
- TUFM | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs373374645; called by muse, mutect2, varscan2
- UNC13A | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV53190120, COSV99408569; called by muse, mutect2, varscan2
- VSTM1 | c.463A>C p.I155L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58074113; called by muse, mutect2
- ZNF274 | c.560A>G p.H187R (on ENST00000610905; = p.H82R on NM_016324.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV58763380; called by muse, mutect2, varscan2
- ZNF34 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58638453; called by muse, mutect2, varscan2
- ZNF536 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 69/102 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs778721262, COSV62820134, COSV62828729; called by muse, mutect2, varscan2
- ALPK3 | c.454_465del p.A152_Q155del | In Frame Del (DEL) | VAF 19/105 reads (18%) | called by mutect2, pindel, varscan2
- FAM163B | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARAP3 | c.1395C>A p.A465= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV53349214; called by muse, mutect2, varscan2
- CFAP65 | c.1296T>C p.T432= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV55389661; called by muse, mutect2, varscan2
- CLDN18 | c.393T>C p.C131= | Silent (SNP) | VAF 52/301 reads (17%) | catalogued as COSV51736011; called by muse, mutect2, varscan2
- ELAVL2 | c.873C>T p.I291= | Silent (SNP) | VAF 74/97 reads (76%) | catalogued as COSV56358600; called by muse, mutect2, varscan2
- FCRL3 | c.1980G>A p.P660= | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as rs370292899, COSV63843916; called by muse, mutect2, varscan2
- FREM1 | c.1947G>A p.R649= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV66519153; called by muse, mutect2, varscan2
- GUCA1C | c.12C>A p.G4= | Silent (SNP) | VAF 57/172 reads (33%) | catalogued as COSV51715743; called by muse, mutect2, varscan2
- IGFN1 | c.1767G>A p.V589= (on ENST00000295591 / NM_001367841.1; = p.V3046= on NM_001164586.2) | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV55167696; called by muse, mutect2, varscan2
- IL10RA | c.753C>T p.A251= | Silent (SNP) | VAF 45/63 reads (71%) | catalogued as COSV57139931; called by muse, mutect2, varscan2
- IMP4 | c.750C>T p.R250= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs551991236, COSV52091326; called by muse, mutect2, varscan2
- MAL | c.243G>A p.E81= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV59430879; called by muse, mutect2, varscan2
- MDN1 | c.2631C>T p.F877= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV65518404; called by muse, mutect2, varscan2
- MGAT3 | c.1587C>T p.D529= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1298319779, COSV100361931; called by muse, mutect2, varscan2
- MKI67 | c.1629T>C p.T543= | Silent (SNP) | VAF 57/210 reads (27%) | catalogued as COSV64073084; called by muse, mutect2, varscan2
- MUC2 | c.1206C>T p.F402= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs767971084; called by muse, mutect2, varscan2
- MYO1A | c.2463G>A p.Q821= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as rs778321558, COSV55652284; called by muse, mutect2, varscan2
- NIBAN1 | c.1539G>A p.A513= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as rs760027367, COSV62283419; called by muse, mutect2, varscan2
- NT5C1A | c.630C>T p.F210= | Silent (SNP) | VAF 44/55 reads (80%) | catalogued as rs752303171, COSV52493475; called by muse, mutect2, varscan2
- OR4K15 | c.121C>T p.L41= (on ENST00000305051; = p.L17= on NM_001005486.1) | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as rs762862872, COSV59300643; called by muse, mutect2, varscan2
- OR4L1 | c.597C>T p.V199= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as COSV59849171; called by muse, mutect2, varscan2
- PABPC1 | c.1809C>T p.L603= | Silent (SNP) | VAF 59/161 reads (37%) | catalogued as rs1373576823, COSV59399191; called by muse, mutect2, varscan2
- PABPC3 | c.42C>T p.Y14= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV55797176, COSV55798143; called by muse, mutect2, varscan2
- PDZD2 | c.279C>T p.F93= | Silent (SNP) | VAF 85/117 reads (73%) | catalogued as rs146790239; called by muse, mutect2, varscan2
- PGC | c.324C>T p.A108= | Silent (SNP) | VAF 77/154 reads (50%) | catalogued as COSV63122317; called by muse, mutect2, varscan2
- RERE | c.3012C>T p.P1004= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100556646; called by muse, mutect2
- S100A7L2 | c.120C>T p.F40= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV64194836; called by muse, mutect2, varscan2
- SIGLEC12 | c.1434G>A p.T478= (on ENST00000291707 / NM_053003.4; = p.T360= on NM_033329.2) | Silent (SNP) | VAF 64/164 reads (39%) | catalogued as rs771612331, COSV52460005; called by muse, mutect2, varscan2
- TADA3 | c.249C>T p.F83= | Silent (SNP) | VAF 47/69 reads (68%) | catalogued as COSV55028116; called by muse, mutect2, varscan2
- TAS2R39 | c.66C>T p.C22= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1476541104, COSV71470823; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.783C>T p.F261= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as COSV59528270; called by muse, mutect2, varscan2
- TRPM2 | c.1233G>A p.R411= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs776838510, COSV55966984; called by muse, mutect2, varscan2
- VWC2L | c.360G>A p.G120= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as rs267599196, COSV56966796; called by muse, mutect2, varscan2
- MRPS17P9 | n.185A>C | RNA (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- POM121 | chr7:72949922 C>T | 3'Flank (SNP) | VAF 19/103 reads (18%) | catalogued as COSV57512062; called by muse, varscan2
- ZNF271P | n.2085G>A | RNA (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
